CCDI case PBCWNP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/5f3e4dad-cf83-49e9-b4cd-1d539df70c0f

Demographics
Sex at birth: male.

Biospecimens (2 samples)
- Sample 0E1KOB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1KON: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
